Gene-level copy-number profile of tumor specimen TCGA-44-6779-01A from TCGA case TCGA-44-6779, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.6 years (18,469 days).
Specimen TCGA-44-6779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1611b412-b41e-4968-b0b6-2767e8c7fe2b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6779-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0acb0ce1-5a27-4773-a98f-6aca8133d76b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 164; copy number 2: 19,169; copy number 3: 16,876; copy number 4: 19,521; copy number 5: 2,296; copy number 6: 1,571; copy number 7: 220.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-6779-01A-11D-1854-01): tumor purity 0.6, ploidy 1.58, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 164 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,906,695–77,649,964, 1 gene (within-gene range 0–2): ROBO2.
- chr3:76,434,018–90,257,415, 87 genes (broad region; genes not listed).
- chr9:21,304,326–23,438,700, 41 genes (within-gene range 0–2): IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr12:43,353,866–45,908,040, 35 genes: ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,637 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:193,473,224–194,931,310, 9 genes, copy number 5 (within-gene range 4–5): AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, AL353072.2.
- chr3:177,816,865–178,385,479, 6 genes, copy number 5: LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1.
- chr8:81,605,569–81,924,348, 13 genes, copy number 5 (within-gene range 4–5): IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235.
- chr8:82,098,451–82,160,577, 1 gene, copy number 5: LINC02839.
- chr8:94,487,689–94,896,678, 18 genes, copy number 5: VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1.
- chr8:94,925,972–94,951,396, 2 genes, copy number 5: TP53INP1, AC087752.3.
- chr8:120,913,065–121,380,465, 3 genes, copy number 5 (within-gene range 4–5): AC068413.1, AC011626.1, RPL35AP19.
- chr12:53,326,575–69,699,476, 495 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:73,115,957–75,984,015, 37 genes, copy number 6 (within-gene range 2–6): AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr12:108,589,851–110,218,793, 51 genes, copy number 5: TMEM119, SELPLG, AC007569.1, MIR4496, CORO1C, RNU7-169P, Y_RNA, AC087893.1, SSH1, AC087893.3, AC087893.2, MIR619, DAO, SVOP, RNU6-361P, AC190387.1, USP30, USP30-AS1, RNA5SP372, ALKBH2, UNG, AC007637.1, ACACB, FOXN4, MYO1H, LINC01486, AC007570.1, KCTD10, UBE3B, MMAB, RNU4-32P, MVK, RN7SKP250, FAM222A, FAM222A-AS1, TRPV4, MIR4497, GLTP, AC007834.2, RN7SL441P, AC007834.1, TCHP, GIT2, AC084876.1, AC084876.2, ANKRD13A, C12orf76, AC007546.1, AC007546.3, AC007546.2, IFT81.
- chr12:115,810,359–116,908,627, 26 genes, copy number 6 (within-gene range 4–6): LINC02463, AC012157.1, AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1, AC079384.2, AC079384.1, MIR4472-2, LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2, AC125603.1, SPRING1, RNFT2, AC090013.1, RNU6-558P, AC083806.3, HRK, AC083806.1.
- chr16:46,469,341–82,575,518, 895 genes, copy number 6 (broad region; genes not listed).
- chr16:82,688,931–82,829,638, 3 genes, copy number 6 (within-gene range 4–6): MIR8058, AC099506.2, AC099506.1.
- chr16:84,699,986–90,222,851, 202 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:60,135,039–83,095,122, 744 genes, copy number 5 (broad region; genes not listed).
- chr20:31,257,664–34,698,790, 132 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
